Somatic mutation profile of tumor specimen C3L-04084-04 (aliquot CPT0217100006) from CPTAC case C3L-04084, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.7 years (23,267 days).
Specimen C3L-04084-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ce47892-69b6-4596-9bf3-be9c0e8d0acb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04084-31 (Blood Derived Normal), aliquot CPT0218020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a976cb19-f478-47c3-a58e-f45b9d8528b3

The open-access MAF lists 77 somatic variants for this specimen: 59 protein-altering or splice-affecting, 11 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 11, Frame Shift Del 4, Intron 3, RNA 3, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF26B | c.6071G>A p.R2024H | Missense Mutation (SNP) | VAF 56/163 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199933797, COSV63638897; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 40/98 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.151); catalogued as rs1257848735, CD105295; called by muse, mutect2, varscan2
- AC011005.1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 72/707 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as rs771131597; called by muse, mutect2, varscan2
- CCDC150 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as rs548240746, COSV55874234; called by muse, mutect2, varscan2
- CDHR5 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 110/245 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.806); catalogued as rs559963181; called by muse, mutect2, varscan2
- DENND5B | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60905390; called by muse, mutect2, varscan2
- DOCK6 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 123/440 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1162772773, COSV52949801; called by muse, mutect2, varscan2
- DRP2 | c.2666C>T p.S889L | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs34562102, COSV101235283, COSV67870604; called by muse, mutect2, varscan2
- FAM71B | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 185/423 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV100262197; called by muse, mutect2, varscan2
- FLI1 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 133/293 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1175896968; called by muse, mutect2, varscan2
- HCFC1 | c.3271G>A p.A1091T | Missense Mutation (SNP) | VAF 71/223 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.413); catalogued as rs1557114364; called by muse, mutect2, varscan2
- IGDCC3 | c.2095C>T p.R699W | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs369729407; called by muse, mutect2, varscan2
- JPH2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 185/632 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); catalogued as rs1475379949, COSV65905469; called by muse, mutect2, varscan2
- JPH3 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 83/180 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567595736, COSV52465027; called by muse, mutect2
- MED12 | c.5576G>A p.R1859H | Missense Mutation (SNP) | VAF 188/484 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.991); catalogued as rs763700798, COSV61347042; called by muse, mutect2, varscan2
- MEOX1 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs150792046; called by muse, mutect2, varscan2
- NMT1 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 124/325 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs771441667; called by muse, mutect2, varscan2
- OCSTAMP | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 102/366 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); catalogued as rs369681916; called by muse, mutect2, varscan2
- OR5A1 | c.521C>A p.P174H | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57378158; called by muse, mutect2
- PAX1 | c.1318C>A p.P440T | Missense Mutation (SNP) | VAF 160/620 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as rs1320181878; called by muse, mutect2, varscan2
- PCDHB3 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 402/965 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.263); catalogued as COSV99166859; called by muse, mutect2, varscan2
- PEDS1 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 102/472 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs146935829; called by muse, mutect2, varscan2
- PHKA2 | c.3206G>A p.R1069H | Missense Mutation (SNP) | VAF 193/429 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs779456044; called by muse, mutect2, varscan2
- PLA2G7 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs200057649, COSV51262044; called by muse, mutect2, varscan2
- PLCH2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 89/192 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760532972, COSV53940727; called by muse, mutect2, varscan2
- PRDM15 | c.3346G>A p.G1116S | Missense Mutation (SNP) | VAF 229/564 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs769745019, COSV99520417; called by muse, mutect2, varscan2
- RFPL2 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 195/466 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs775316477; called by muse, mutect2, varscan2
- RPL3L | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 96/214 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs374360894, COSV51905181; called by muse, mutect2, varscan2
- SH2B3 | c.1135C>G p.Q379E | Missense Mutation (SNP) | VAF 390/840 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1332773263, COSV57982333; called by muse, mutect2, varscan2
- SH3RF2 | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs747775775, COSV63037307; called by muse, mutect2, varscan2
- SLC17A4 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 127/298 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747535097, COSV100930484, COSV64957451; called by muse, mutect2, varscan2
- SLC22A4 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 87/480 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1198530094; called by muse, mutect2, varscan2
- SUCLG1 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 24/551 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs201224138; ClinVar: uncertain significance; called by muse, mutect2
- TASOR2 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as rs764998702, COSV60168576; called by muse, mutect2, varscan2
- TCEANC2 | c.363A>C p.E121D | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1271041773; called by muse, mutect2, varscan2
- TLE1 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs771899498; called by muse, mutect2, varscan2
- TMLHE | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV57686925; called by muse, mutect2
- XKR5 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 72/146 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368056834; called by muse, mutect2, varscan2
- ZDHHC4 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 253/824 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781761812, COSV60105939; called by muse, mutect2, varscan2
- ADCY5 | c.1193A>G p.Y398C | Missense Mutation (SNP) | VAF 107/269 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- ANKRD33B | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD36B | c.1446A>C p.R482S | Missense Mutation (SNP) | VAF 84/534 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- ASNS | c.1529del p.P510Lfs*24 | Frame Shift Del (DEL) | VAF 114/453 reads (25%) | called by mutect2, pindel, varscan2
- C6 | c.2269A>C p.N757H | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- CLCA4 | c.184T>C p.Y62H | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNKSR2 | c.283T>C p.S95P | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- COL27A1 | c.1151del p.S384Tfs*74 | Frame Shift Del (DEL) | VAF 226/508 reads (44%) | called by mutect2, pindel, varscan2
- CSF2RA | c.810+8A>C | Splice Region (SNP) | VAF 88/488 reads (18%) | called by muse, varscan2
- CWC22 | c.712A>C p.I238L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ECE1 | c.2231C>T p.S744F | Missense Mutation (SNP) | VAF 142/292 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FGR | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MPST | c.280G>A p.A94T (on ENST00000341116 / NM_001369904.2; = p.A114T on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 177/418 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- NF1 | c.6547_6548del p.R2183Gfs*10 (on ENST00000358273 / NM_001042492.3; = p.R2162Gfs*10 on NM_000267.3) | Frame Shift Del (DEL) | VAF 84/222 reads (38%) | called by mutect2, pindel, varscan2
- RELN | c.161A>C p.E54A | Missense Mutation (SNP) | VAF 134/534 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- SLC36A1 | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 118/270 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STX16 | c.720del p.R241Afs*10 (on ENST00000371141 / NM_001001433.3; = p.R220Afs*10 on NM_003763.6) | Frame Shift Del (DEL) | VAF 38/178 reads (21%) | called by mutect2, pindel, varscan2
- TTC6 | c.772G>T p.G258C (on ENST00000267368; = p.G1624C on NM_001310135.3) | Missense Mutation (SNP) | VAF 53/342 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- WDR64 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- ADGRD2 | c.2733C>T p.Y911= | Silent (SNP) | VAF 129/415 reads (31%) | catalogued as rs537070341, COSV100601271; called by muse, mutect2, varscan2
- ATP2A3 | c.2709G>A p.V903= | Silent (SNP) | VAF 193/572 reads (34%) | catalogued as rs1203392933, COSV59227602; called by muse, varscan2
- CRNN | c.342C>T p.G114= | Silent (SNP) | VAF 69/183 reads (38%) | catalogued as rs776277743; called by muse, mutect2, varscan2
- ENGASE | c.336G>A p.A112= | Silent (SNP) | VAF 201/492 reads (41%) | catalogued as rs368771548, COSV56134442; called by muse, mutect2, varscan2
- OR10G8 | c.9C>T p.N3= | Silent (SNP) | VAF 53/134 reads (40%) | catalogued as rs1276314044, COSV70908448; called by muse, mutect2
- PLEKHN1 | c.1062C>T p.Y354= (on ENST00000379409; = p.Y302= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 122/318 reads (38%) | catalogued as rs771647949; called by muse, mutect2, varscan2
- PLXNA3 | c.2202C>T p.A734= | Silent (SNP) | VAF 189/434 reads (44%) | catalogued as rs370105284; ClinVar: likely benign; called by muse, mutect2, varscan2
- RPTN | c.1050C>T p.G350= | Silent (SNP) | VAF 235/527 reads (45%) | called by muse, mutect2, varscan2
- SAV1 | c.399T>C p.Y133= | Silent (SNP) | VAF 97/230 reads (42%) | called by muse, mutect2, varscan2
- TEX101 | c.57C>A p.L19= (on ENST00000598265 / NM_001130011.3; = p.L37= on NM_031451.4) | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as COSV99494784; called by muse, mutect2, varscan2
- UCK2 | c.762G>A p.S254= | Silent (SNP) | VAF 72/181 reads (40%) | catalogued as rs758851382; called by muse, mutect2, varscan2
- C3P1 | n.2461G>A | RNA (SNP) | VAF 90/325 reads (28%) | catalogued as rs754094244; called by muse, mutect2, varscan2
- CASZ1 | c.2681-26C>T | Intron (SNP) | VAF 11/36 reads (31%) | catalogued as rs200980171; called by muse, mutect2, varscan2
- CD37 | chr19:49331790 C>T | 5'Flank (SNP) | VAF 20/299 reads (7%) | called by muse, mutect2
- ESRRG | c.56+15832T>C | Intron (SNP) | VAF 77/210 reads (37%) | catalogued as rs531289758; called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.1372C>T | RNA (SNP) | VAF 191/616 reads (31%) | called by muse, varscan2
- MIR1283-2 | n.39del | RNA (DEL) | VAF 93/283 reads (33%) | called by mutect2, pindel, varscan2
- SGIP1 | c.472-1233T>C | Intron (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
